Somatic mutation profile of tumor specimen TARGET-20-PASUMD-04A (aliquot TARGET-20-PASUMD-04A-01D) from TARGET case TARGET-20-PASUMD, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,307 days).
Specimen TARGET-20-PASUMD-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0418ed44-6f2f-4b99-9d20-8f77525a0a3b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASUMD-14A (Bone Marrow Normal), aliquot TARGET-20-PASUMD-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/affa37b6-0af4-44d6-9631-b1e192d7fd54

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TRIM24 | c.2503G>A p.G835R (on ENST00000343526 / NM_015905.3; = p.G801R on NM_003852.4) | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100630755, COSV100630950; called by muse, mutect2, varscan2
- TDRD6 | c.-12C>T | 5'UTR (SNP) | VAF 9/20 reads (45%) | catalogued as COSV60178436; called by muse, mutect2, varscan2
